EXCEPTIONAL_RESPONDERS case ER-B0EH — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Anus and anal canal. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4266958e-cd40-4b96-b689-7c0d7ca18507

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1933; Vital status: Alive.

Diagnoses (2)
1. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Anus, NOS; Site of resection or biopsy: Anus, NOS; Classification of tumor: primary; Age at diagnosis: 79.9 years (29,195 days); Year of diagnosis: 2013; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 1,369 days (3.7 years); Days to best overall response: 158 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Ipilimumab; Days to treatment start: 72 days; Days to treatment end: 135 days.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Blood; Age at diagnosis: 76.7 years (28,004 days); AJCC pathologic stage: Stage 0.

Follow-up (1 entry)
- Days to follow up: 1,369 days (3.7 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,369 days (3.7 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0EH-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0EH-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 27; Percent lymphocyte infiltration: 16; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
- Sample ER-B0EH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0EH-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 6.
